Somatic mutation profile of tumor specimen TCGA-KB-A93J-01A (aliquot TCGA-KB-A93J-01A-11D-A397-08) from TCGA case TCGA-KB-A93J, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 78.3 years (28,599 days).
Specimen TCGA-KB-A93J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 254290bc-0865-46a8-984a-243086186c82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KB-A93J-10A (Blood Derived Normal), aliquot TCGA-KB-A93J-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da6eb509-f300-4b96-baba-8234a410c147

The open-access MAF lists 163 somatic variants for this specimen: 153 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 38, Frame Shift Del 37, Missense Mutation 31, In Frame Del 19, Splice Site 10, In Frame Ins 9, Nonsense Mutation 6, Silent 6, Splice Region 2, 5'Flank 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.155_158dup p.W53* | Nonsense Mutation (INS) | VAF 76/148 reads (51%) | hotspot (GDC flag); catalogued as rs1195793509, COSV99390761; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AP5M1 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs745558945, COSV99841155, COSV99841264; called by muse, mutect2, varscan2
- ARHGAP32 | c.3159A>C p.Q1053H (on ENST00000310343 / NM_001378025.1; = p.Q704H on NM_014715.4) | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs1419386021, COSV100087523; called by muse, mutect2, varscan2
- AXL | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56573239; called by muse, mutect2
- BUD31 | c.217+4dup | Splice Region (INS) | VAF 24/82 reads (29%) | catalogued as rs1467957938; called by mutect2, pindel, varscan2
- C1orf116 | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as rs1456735358, COSV100847913; called by muse, mutect2, varscan2
- CFH | c.2956+1G>A p.X986_splice | Splice Site (SNP) | VAF 40/115 reads (35%) | catalogued as CS100541, COSV100809347; called by muse, mutect2, varscan2
- DIAPH1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99526354; called by muse, mutect2, varscan2
- FAM160B1 | c.2100C>A p.D700E | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.148); catalogued as COSV100985404; called by muse, mutect2, varscan2
- FBXO28 | c.476A>C p.K159T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100837405; called by muse, mutect2, varscan2
- FLG | c.7940G>T p.R2647I | Missense Mutation (SNP) | VAF 77/582 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.267); catalogued as COSV100911460; called by muse, mutect2, varscan2
- FLG | c.3707G>A p.R1236H | Missense Mutation (SNP) | VAF 117/331 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs201976711; called by muse, mutect2, varscan2
- FOXE1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1441439043, COSV64301125; called by muse, mutect2, varscan2
- GPX3 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.169); catalogued as COSV101183623; called by muse, mutect2
- HAO1 | c.577T>G p.F193V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as COSV101113184; called by muse, mutect2, varscan2
- HTR3B | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1352663541, COSV52742639, COSV99491908; called by muse, mutect2, varscan2
- KDM4C | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs918778929, COSV101184775; called by muse, mutect2, varscan2
- MMP16 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 79/220 reads (36%) | catalogued as COSV54182752; called by muse, mutect2, varscan2
- NCOA2 | c.2968A>G p.M990V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1262386218, COSV99144770; called by muse, mutect2, varscan2
- OR1J4 | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); catalogued as COSV100534266, COSV61589749; called by muse, mutect2, varscan2
- PCDHA7 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV65344678; called by muse, mutect2, varscan2
- PCDHA9 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.029); catalogued as COSV65326387; called by muse, mutect2
- PTPDC1 | c.1413dup p.S472Vfs*42 (on ENST00000375360 / NM_177995.3; = p.S524Vfs*42 on NM_152422.4) | Frame Shift Ins (INS) | VAF 9/37 reads (24%) | catalogued as rs1189128575; called by mutect2, pindel, varscan2
- RFX4 | c.1001G>A p.R334Q (on ENST00000392842 / NM_213594.3; = p.R240Q on NM_032491.6) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs963454961, COSV57573846; called by muse, mutect2, varscan2
- RYR2 | c.13696G>A p.G4566S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs767716570, COSV100769525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEZ6 | c.1246T>A p.C416S | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100252950; called by muse, mutect2, varscan2
- SLIT3 | c.1622A>G p.D541G | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV100266772; called by muse, mutect2, varscan2
- STOML2 | c.116_117insA p.F40Vfs*49 | Frame Shift Ins (INS) | VAF 21/73 reads (29%) | catalogued as COSV100521269; called by mutect2, pindel, varscan2
- TAAR2 | c.587C>T p.A196V (on ENST00000367931 / NM_001033080.1; = p.A151V on NM_014626.3) | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.844); catalogued as rs143686646; called by muse, mutect2, varscan2
- TGFB1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV55723860; called by muse, mutect2, varscan2
- THAP3 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs925967261, COSV50011182; called by muse, mutect2
- TMC7 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as COSV100432423; called by muse, mutect2, varscan2
- TOP2A | c.2229G>T p.K743N | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV70732591; called by muse, mutect2, varscan2
- TOR1B | c.941dup p.R316Qfs*64 | Frame Shift Ins (INS) | VAF 27/82 reads (33%) | catalogued as rs1564179273; called by mutect2, pindel, varscan2
- TP53BP1 | c.2036T>C p.L679P | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1379251443, COSV55510867, COSV99780297; called by muse, mutect2, varscan2
- TTLL5 | c.2212C>T p.R738* | Nonsense Mutation (SNP) | VAF 56/173 reads (32%) | catalogued as rs377702881, COSV100089828; called by muse, mutect2, varscan2
- TYW5 | c.680dup p.L227Ffs*10 | Frame Shift Ins (INS) | VAF 34/113 reads (30%) | catalogued as rs768992736; called by mutect2, pindel, varscan2
- USP15 | c.2676T>C p.Y892= (on ENST00000280377 / NM_001351159.2; = p.Y863= on NM_006313.3 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 21/66 reads (32%) | catalogued as rs1462419307, COSV99739203; called by muse, mutect2, varscan2
- WDR20 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 36/101 reads (36%) | catalogued as COSV100084960; called by muse, mutect2, varscan2
- WNK1 | c.2558_2559insAG p.A854Gfs*51 | Frame Shift Ins (INS) | VAF 24/58 reads (41%) | catalogued as COSV100267008; called by mutect2, pindel, varscan2
- ZNF350 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138780746; called by muse, mutect2, varscan2
- ZNF471 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs142290015; called by muse, mutect2, varscan2
- ZNF536 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs75311223, COSV100835060; called by mutect2, varscan2
- ABHD8 | c.1027_1030dup p.G344Efs*29 | Frame Shift Ins (INS) | VAF 27/65 reads (42%) | called by mutect2, pindel, varscan2
- ACSS1 | c.1167_1170delinsA p.A390del | In Frame Del (DEL) | VAF 17/90 reads (19%) | called by pindel, varscan2*
- ADGRE5 | c.2344_2347dup p.Y783Sfs*105 (on ENST00000242786 / NM_078481.4; = p.Y690Sfs*105 on NM_001784.5) | Frame Shift Ins (INS) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- ADGRG5 | c.298-6_327del p.X100_splice | Splice Site (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel*
- ADRB2 | c.4_7del p.G2Nfs*94 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by mutect2, pindel
- AFDN | c.1009+2_1009+8delinsATTA p.X337_splice | Splice Site (DEL) | VAF 36/79 reads (46%) | called by pindel, varscan2*
- AGO4 | c.185+1_185+17del p.X62_splice | Splice Site (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- AIFM1 | c.234_245del p.G79_A82del | In Frame Del (DEL) | VAF 55/95 reads (58%) | called by mutect2, pindel, varscan2
- ANK3 | c.1977_1979delinsC p.V660Yfs*26 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | called by pindel, varscan2*
- ANKRD35 | c.1154_1157dup p.K386Nfs*21 | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- ARHGAP26 | c.340_343dup p.P115Hfs*22 | Frame Shift Ins (INS) | VAF 34/81 reads (42%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.2539del p.C847Vfs*12 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
- BID | c.434_438del p.R145Hfs*40 (on ENST00000317361 / NM_197966.2; = p.R99Hfs*40 on NM_001196.4) | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel
- C10orf90 | c.983dup p.D329Gfs*51 | Frame Shift Ins (INS) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- CAPN2 | c.1591_1594del p.D531Mfs*26 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- CASR | c.2098_2111del p.I700Pfs*22 (on ENST00000490131; = p.I777Pfs*22 on NM_000388.4) | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- CCDC183 | c.492_501del p.Q166Tfs*11 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- CCNG2 | c.368dup p.H123Qfs*2 | Frame Shift Ins (INS) | VAF 37/141 reads (26%) | called by mutect2, pindel, varscan2
- CDC42BPA | c.2950_2951dup p.D984Efs*13 (on ENST00000334218 / NM_001366019.2; = p.D971Efs*13 on NM_003607.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 46/124 reads (37%) | called by mutect2, pindel, varscan2
- CELSR3 | c.4913_4916dup p.A1640Rfs*8 | Frame Shift Ins (INS) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- CLMP | c.670_675del p.T224_V225del | In Frame Del (DEL) | VAF 39/108 reads (36%) | called by mutect2, pindel, varscan2
- COG1 | c.2228_2238del p.W743Ffs*5 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | called by mutect2, pindel, varscan2
- CPED1 | c.1_6del p.MV1_?2 | Translation Start Site (DEL) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- CPSF1 | c.1876_1879dup p.R627Hfs*48 | Frame Shift Ins (INS) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- CSF1R | c.500_504del p.A167Vfs*62 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- CSNK2A2 | c.195_196dup p.V66Efs*4 | Frame Shift Ins (INS) | VAF 61/217 reads (28%) | called by mutect2, varscan2
- CSTF2T | c.1642del p.I548Yfs*32 | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | called by mutect2, varscan2*
- DIMT1 | c.135_146del p.N46_I49del | In Frame Del (DEL) | VAF 32/111 reads (29%) | called by mutect2, pindel, varscan2
- DNTTIP1 | c.406_408dup p.I136dup | In Frame Ins (INS) | VAF 48/170 reads (28%) | called by mutect2, pindel, varscan2
- DUOX1 | c.2624_2627dup p.F876Lfs*24 | Frame Shift Ins (INS) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- E2F4 | c.782dup p.M261Ifs*7 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- ECH1 | c.353_356del p.I118Tfs*2 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- EEA1 | c.1806_1811del p.E604_Q605del | In Frame Del (DEL) | VAF 61/128 reads (48%) | called by mutect2, pindel, varscan2
- ELP1 | c.1311_1326del p.N437Kfs*22 | Frame Shift Del (DEL) | VAF 10/105 reads (10%) | called by mutect2, pindel
- EPS8L2 | c.292_295del p.D98Sfs*87 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- ERBB3 | c.4012_4014dup p.N1338dup | In Frame Ins (INS) | VAF 46/153 reads (30%) | called by mutect2, pindel, varscan2
- FBXO21 | c.1209_1212dup p.Y405Vfs*49 (on ENST00000330622 / NM_033624.3; = p.Y405Vfs*42 on NM_015002.3) | Frame Shift Ins (INS) | VAF 23/86 reads (27%) | called by mutect2, pindel, varscan2
- FKBP8 | c.300dup p.L101Afs*49 | Frame Shift Ins (INS) | VAF 33/134 reads (25%) | called by mutect2, pindel, varscan2
- GIPR | c.838_843del p.L280_Y281del | In Frame Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- GJA9 | c.124_154del p.E42Sfs*31 | Frame Shift Del (DEL) | VAF 60/266 reads (23%) | called by mutect2, pindel
- GOLGA3 | c.954_956dup p.S319dup | In Frame Ins (INS) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.4355del p.E1452Gfs*3 | Frame Shift Del (DEL) | VAF 79/286 reads (28%) | called by mutect2, pindel, varscan2
- GPATCH2 | c.1101_1103del p.P368del | In Frame Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- GPATCH2L | c.1193+3_1193+8del p.X398_splice | Splice Site (DEL) | VAF 31/130 reads (24%) | called by mutect2, pindel, varscan2
- GSDMD | c.58_65del p.G20Hfs*20 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel
- GZF1 | c.1459+4_1459+7del p.X487_splice | Splice Site (DEL) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- HEATR3 | c.1943dup p.N648Kfs*3 | Frame Shift Ins (INS) | VAF 39/127 reads (31%) | called by mutect2, pindel, varscan2
- HECTD3 | c.726_728dup p.Q242_Y243ins* | Nonsense Mutation (INS) | VAF 20/69 reads (29%) | called by mutect2, pindel, varscan2
- HLA-B | c.719_720del p.T240Mfs*13 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- HRCT1 | c.141_143del p.A48del | In Frame Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- IFT172 | c.4713_4714del p.P1572Cfs*7 | Frame Shift Del (DEL) | VAF 25/68 reads (37%) | called by pindel, varscan2
- INPP5D | c.2184dup p.G729Rfs*4 (on ENST00000445964 / NM_001017915.3; = p.G728Rfs*4 on NM_005541.5) | Frame Shift Ins (INS) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- ITGAV | c.458_459dup p.P154Sfs*86 | Frame Shift Ins (INS) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- ITPRID2 | c.2488_2491del p.T830Vfs*35 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- KCNK5 | c.999dup p.L334Afs*41 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- KDM6A | c.3667_3670del p.G1223Lfs*41 | Frame Shift Del (DEL) | VAF 24/36 reads (67%) | called by mutect2, pindel, varscan2
- LGR5 | c.198_201del p.F67Pfs*4 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel
- LHFPL4 | c.497_499dup p.Y166dup | In Frame Ins (INS) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- LIPH | c.137dup p.Y46* | Nonsense Mutation (INS) | VAF 52/189 reads (28%) | called by mutect2, pindel, varscan2
- MAN1A1 | c.860_885del p.G287Vfs*76 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, pindel
- MAP4K4 | c.593_605del p.E198Vfs*38 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- MAPK3 | c.406_407dup p.Q136Hfs*4 | Frame Shift Ins (INS) | VAF 26/82 reads (32%) | called by mutect2, pindel, varscan2
- MATN3 | c.452dup p.R152Sfs*35 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- MCL1 | c.479_481dup p.L160dup | In Frame Ins (INS) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- MED13 | c.189_192dup p.V65Rfs*24 | Frame Shift Ins (INS) | VAF 64/213 reads (30%) | called by mutect2, pindel, varscan2
- MUC16 | c.16547_16579del p.I5516_S5526del | In Frame Del (DEL) | VAF 26/76 reads (34%) | called by mutect2, pindel
- MYCBP2 | c.12281_12292del p.A4094_T4097del (on ENST00000357337; = p.A4132_T4135del on NM_015057.5) | In Frame Del (DEL) | VAF 49/220 reads (22%) | called by mutect2, pindel, varscan2
- NAPSA | c.614del p.V205Dfs*61 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel*, varscan2
- NEK9 | c.992del p.S331* | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- NEURL2 | c.722_727del p.L241_V242del | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- NEUROD2 | c.441_444del p.V148Pfs*17 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- NOMO1 | c.1397_1398insCAT p.M467dup | In Frame Ins (INS) | VAF 40/120 reads (33%) | called by pindel, varscan2
- NOTCH4 | c.4801_4802dup p.Q1601Hfs*106 | Frame Shift Ins (INS) | VAF 8/17 reads (47%) | called by mutect2, pindel, varscan2
- NR1D2 | c.1113_1114del p.S371Rfs*17 | Frame Shift Del (DEL) | VAF 34/68 reads (50%) | called by mutect2, pindel, varscan2
- NSUN5 | c.94-15_129del p.X32_splice | Splice Site (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel
- NUDT22 | c.880dup p.L294Pfs*? | Frame Shift Ins (INS) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- P2RY6 | c.524_525dup p.V176Lfs*184 | Frame Shift Ins (INS) | VAF 26/75 reads (35%) | called by mutect2, pindel, varscan2
- PAIP1 | c.667_669del p.N223del | In Frame Del (DEL) | VAF 27/79 reads (34%) | called by mutect2, pindel, varscan2
- PCBP1 | c.1062dup p.C355Vfs*11 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- PGP | c.651_654dup p.V219Sfs*75 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- PLBD2 | c.1057_1060delinsT p.N353_R354delinsC | In Frame Del (DEL) | VAF 14/35 reads (40%) | called by pindel, varscan2*
- PMPCB | c.101_106del p.S34_L35del | In Frame Del (DEL) | VAF 97/305 reads (32%) | called by mutect2, pindel, varscan2
- POP5 | c.33_37del p.E12Gfs*3 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- PPFIA3 | c.1524_1527dup p.P510Sfs*71 | Frame Shift Ins (INS) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- PRKG1 | c.166_168del p.A56del | In Frame Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- RAB2B | c.429_431dup p.I144dup | In Frame Ins (INS) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- RBM46 | c.1291_1296delinsCA p.V431Hfs*21 | Frame Shift Del (DEL) | VAF 24/55 reads (44%) | called by pindel, varscan2*
- RPL8 | c.397dup p.Y133Lfs*10 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | called by mutect2, varscan2
- RPL8 | c.390_395del p.G131_N132del | In Frame Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel*, varscan2
- RSRC1 | c.650_652+7del p.X217_splice | Splice Site (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- SH3YL1 | c.604dup p.D202Gfs*4 | Frame Shift Ins (INS) | VAF 15/67 reads (22%) | called by mutect2, pindel, varscan2
- SIRPB2 | c.903_907delinsC p.I302Pfs*30 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by pindel, varscan2*
- SP140 | c.618_620dup p.G208dup | In Frame Ins (INS) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- STK33 | c.1514_1516dup p.G505dup | In Frame Ins (INS) | VAF 50/207 reads (24%) | called by mutect2, pindel, varscan2
- STX10 | c.176_179del p.W59Sfs*11 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- SUGP2 | c.1522_1530del p.A508_S510del | In Frame Del (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- TBC1D2 | c.1308_1309dup p.P437Lfs*13 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- TBC1D3F | c.280-2_289del p.X94_splice | Splice Site (DEL) | VAF 56/164 reads (34%) | called by mutect2, varscan2
- TOM1 | c.797_799del p.Q266del | In Frame Del (DEL) | VAF 14/42 reads (33%) | called by pindel, varscan2
- TSPAN10 | c.930_933dup p.V312Sfs*167 (on ENST00000574882 / NM_001290212.1; = p.V274Sfs*? on NM_031945.4) | Frame Shift Ins (INS) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- TUBGCP4 | c.187_188del p.T63Gfs*43 | Frame Shift Del (DEL) | VAF 25/100 reads (25%) | called by pindel, varscan2
- UHRF1 | c.697_701del p.K233Afs*30 (on ENST00000612630 / NM_001290050.1; = p.K246Afs*30 on NM_013282.4) | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- VCAN | c.6975dup p.S2326Vfs*13 | Frame Shift Ins (INS) | VAF 31/115 reads (27%) | called by mutect2, pindel, varscan2
- VCP | c.32_33del p.D11Afs*18 | Frame Shift Del (DEL) | VAF 54/182 reads (30%) | called by mutect2, pindel, varscan2
- VPS13B | c.1651+3_1651+4dup p.X551_splice | Splice Site (INS) | VAF 50/178 reads (28%) | called by mutect2, pindel, varscan2
- ZC3HAV1 | c.1741_1743del p.C581del | In Frame Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel
- ZFP57 | c.130_131del p.V44Hfs*3 | Frame Shift Del (DEL) | VAF 39/108 reads (36%) | called by mutect2, pindel, varscan2
- ZNF407 | c.4313dup p.T1439Yfs*27 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- ZNF529 | c.1433_1439del p.Y478Lfs*89 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | called by mutect2, pindel, varscan2
- ZNF692 | c.685_686del p.L229Afs*9 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel
- ARHGEF7 | c.1437C>T p.N479= (on ENST00000375741 / NM_001113511.2; = p.N301= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs769870955, COSV99521378; called by muse, mutect2, varscan2
- CTNNA2 | c.2614C>T p.L872= (on ENST00000402739 / NM_001282597.3; = p.L824= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as COSV100560084; called by muse, mutect2, varscan2
- IGSF9B | c.198G>A p.G66= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1466974594, COSV100317413; called by muse, mutect2
- OR8D1 | c.609G>A p.A203= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as rs148861414; called by muse, mutect2, varscan2
- PCDHGA2 | c.1911G>A p.A637= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs763228700, COSV99535842; called by muse, mutect2, varscan2
- TSSK2 | c.687G>A p.K229= | Silent (SNP) | VAF 4/67 reads (6%) | catalogued as COSV52816609; called by muse, mutect2
- AL645933.1 | chr6:31463925 ins A | 5'Flank (INS) | VAF 36/68 reads (53%) | called by mutect2, pindel*, varscan2
- MIR17 | n.35_42del | RNA (DEL) | VAF 68/169 reads (40%) | called by mutect2, pindel, varscan2
- PNPO | c.417+294G>A | Intron (SNP) | VAF 16/41 reads (39%) | catalogued as COSV56667062; called by muse, mutect2, varscan2
- STEAP2 | c.*1_*2insATCA | 3'UTR (INS) | VAF 13/37 reads (35%) | called by mutect2, pindel*
